Gene-level copy-number profile of tumor specimen C3L-00358-01 from CPTAC case C3L-00358, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-00358-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd0965d9-07ea-42b7-9124-687c6951df28.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00358-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/68b54546-f660-4047-86c8-ee398ede5776

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 745; copy number 2: 13,666; copy number 3: 17,611; copy number 4: 16,807; copy number 5: 5,753; copy number 6: 2,099; copy number 7: 1,074; copy number 8: 251; copy number 9: 55; copy number 10: 213; copy number 11: 17; copy number 13: 35; copy number 15: 5; copy number 16: 15; copy number 17: 4.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr8:7,881,392–8,096,726, 18 genes: DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.2, MIR548I3, RPS3AP31.
- chr8:12,333,644–12,436,343, 11 genes: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr16:3,500,976–3,717,553, 10 genes (within-gene range 0–2): CLUAP1, AC004494.2, NLRC3, AC004494.1, AC006111.1, SLX4, DNASE1, AC006111.2, TRAP1, AC006111.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,669 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,275,223–1,434,573, 24 genes, copy number 7–8: LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8, AURKAIP1, NDUFB4P8, CCNL2, MRPL20-AS1, MRPL20, RN7SL657P, MRPL20-DT, ANKRD65, AL391244.1, TMEM88B, LINC01770.
- chr1:143,419,625–152,196,699, 352 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:132,643,286–132,671,579, 2 genes, copy number 9 (within-gene range 4–9): LYPD1, AC010974.1.
- chr2:190,504,338–190,843,734, 6 genes, copy number 7 (within-gene range 3–7): NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1.
- chr3:72,321,051–74,005,609, 28 genes, copy number 7–11: AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047.
- chr3:75,521,803–75,522,012, 1 gene, copy number 10: SNRPCP10.
- chr4:68,509,441–68,616,137, 4 genes, copy number 7: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr4:68,646,597–68,670,652, 1 gene, copy number 7: UGT2B15.
- chr12:54,802,746–56,985,960, 130 genes, copy number 7 (broad region; genes not listed).
- chr16:30,875,222–30,910,208, 6 genes, copy number 7 (within-gene range 3–7): MIR762HG, MIR4519, AC135048.2, MIR762, CTF1, CTF2P.
- chr19:11,322,068–11,346,270, 1 gene, copy number 7 (within-gene range 4–7): RAB3D.
- chr19:11,342,776–11,550,323, 19 genes, copy number 7: TMEM205, CCDC159, PLPPR2, AC024575.1, SWSAP1, EPOR, RGL3, Y_RNA, CCDC151, PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1.
- chr19:28,065,267–28,429,490, 5 genes, copy number 15: AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1.
- chr19:29,811,991–29,921,653, 4 genes, copy number 17: CCNE1, AC008798.1, AC008507.3, PPIAP58.
- chr20:87,250–5,197,887, 161 genes, copy number 8–13 (broad region; genes not listed).
- chr20:5,318,268–6,067,897, 26 genes, copy number 9–16: AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1.
- chr20:10,672,695–21,115,197, 150 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr20:21,488,244–26,251,546, 129 genes, copy number 7–9 (broad region; genes not listed).
- chr20:38,210,503–64,327,972, 620 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 732. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
